Somatic mutation profile of tumor specimen TCGA-86-7701-01A (aliquot TCGA-86-7701-01A-11D-2167-08) from TCGA case TCGA-86-7701, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 66.3 years (24,209 days).
Specimen TCGA-86-7701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de384d7d-2f68-45ac-ad6e-ee851e607aac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-7701-10A (Blood Derived Normal), aliquot TCGA-86-7701-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ec598a0-1c13-46ec-921a-08bed238e017

The open-access MAF lists 208 somatic variants for this specimen: 167 protein-altering or splice-affecting, 37 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 37, Nonsense Mutation 9, Splice Region 4, Frame Shift Del 3, Splice Site 2, 5'UTR 2, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKD1 | c.10348G>T p.E3450* (on ENST00000262304 / NM_001009944.3; = p.E3449* on NM_000296.4) | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs780009030, COSV51922262; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC5A1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs201799893, CM110176, COSV56683485; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.5968G>T p.G1990W | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61366324; called by muse, mutect2, varscan2
- ACTRT1 | c.389T>A p.F130Y | Missense Mutation (SNP) | VAF 97/169 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64419818; called by muse, mutect2, varscan2
- ADAM19 | c.2380C>A p.P794T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.63); catalogued as COSV57436093; called by muse, mutect2, varscan2
- ADAMTS12 | c.3113C>A p.P1038H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV61273049; called by muse, mutect2, varscan2
- ADAMTS14 | c.959T>A p.L320Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as COSV64605010; called by muse, varscan2
- ADCY5 | c.2875G>T p.D959Y | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV100567636, COSV59201837; called by muse, mutect2, varscan2
- ADGRL2 | c.1011G>T p.K337N | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV54680639; called by muse, mutect2, varscan2
- AMPD1 | c.2203G>T p.G735C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62415063, COSV62415300; called by muse, varscan2
- ANKRD30A | c.3958G>T p.D1320Y (on ENST00000611781; = p.D1264Y on NM_052997.2) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV64615520, COSV64617064; called by muse, mutect2, varscan2
- ATP5F1B | c.1319T>G p.I440S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV51641151; called by muse, mutect2
- BCL11A | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100186219; called by muse, mutect2, varscan2
- BCL2L2-PABPN1 | c.1081T>C p.W361R (on ENST00000678502; = p.W329R on NM_001199864.2) | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.99); catalogued as COSV53730109; called by muse, mutect2
- BSCL2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs778486956, COSV54017192; called by muse, mutect2, varscan2
- BTBD10 | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs1286781425, COSV53400722; called by muse, mutect2
- CABIN1 | c.6617C>T p.S2206L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs750516828, COSV54086872; called by muse, mutect2, varscan2
- CACNG6 | c.761A>G p.K254R (on ENST00000252729 / NM_145814.1; = p.K183R on NM_031897.2) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as rs747892500, COSV53167637; called by muse, mutect2, varscan2
- CCDC3 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); catalogued as rs781056077, COSV66561007; called by muse, mutect2, varscan2
- CIITA | c.294C>A p.I98= | Splice Region (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100162439; called by muse, varscan2
- CNTN3 | c.2203G>C p.G735R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99724395; called by muse, mutect2, varscan2
- CNTN5 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.024); catalogued as COSV54285411; called by muse, mutect2, varscan2
- COL12A1 | c.953C>A p.S318* | Nonsense Mutation (SNP) | VAF 59/157 reads (38%) | catalogued as COSV59403724; called by muse, mutect2, varscan2
- COL14A1 | c.154G>C p.A52P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs756367159, COSV52857171, COSV52863535; called by mutect2, varscan2
- CR2 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65508989; called by muse, mutect2
- CRTC2 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.441); catalogued as COSV100339275; called by muse, varscan2
- CRYGA | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV58018413; called by muse, mutect2
- CSMD3 | c.3872G>T p.G1291V (on ENST00000297405 / NM_001363185.1; = p.G1187V on NM_052900.3) | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52114275, COSV52269703; called by muse, mutect2, varscan2
- CSNK1A1L | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs759977373, COSV65789302, COSV65789894, COSV65790611; called by muse, mutect2, varscan2
- CTTNBP2 | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs746241505, COSV50413112; called by muse, mutect2, varscan2
- DCLRE1C | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV63184823; called by muse, mutect2, varscan2
- DENND1A | c.1513G>T p.V505F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV65341708; called by muse, mutect2, varscan2
- DEPDC1 | c.2306A>T p.K769M (on ENST00000456315 / NM_001114120.3; = p.K485M on NM_017779.6) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63958805; called by muse, mutect2, varscan2
- DPP6 | c.2079G>T p.R693= (on ENST00000377770 / NM_001364500.2; = p.R631= on NM_001936.5) | Splice Region (SNP) | VAF 33/94 reads (35%) | catalogued as COSV59635046; called by muse, mutect2, varscan2
- DSEL | c.1512G>T p.L504F | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV59493666; called by muse, mutect2, varscan2
- EBF1 | c.1125G>T p.K375N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58189397; called by mutect2, varscan2
- EDAR | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV51506287; called by muse, mutect2, varscan2
- EIF4G2 | c.2677T>A p.W893R | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60598504; called by muse, mutect2, varscan2
- F2R | c.213A>T p.L71F | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as COSV100058578; called by muse, mutect2, varscan2
- F2R | c.214G>T p.V72F | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV100058582; called by muse, mutect2, varscan2
- F9 | c.1205G>C p.G402A | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.594); catalogued as CM083696, COSV54381878; called by muse, mutect2, varscan2
- FAM151A | c.1560C>A p.S520R | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV56365413; called by muse, mutect2, varscan2
- FBXO43 | c.1648A>T p.I550F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV71055110; called by muse, mutect2, varscan2
- FLG2 | c.2644T>C p.S882P | Missense Mutation (SNP) | VAF 77/658 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs546116163, COSV66171448; called by muse, mutect2, varscan2
- FLNC | c.6719A>C p.Q2240P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57961547; called by muse, mutect2
- FNDC8 | c.461T>A p.L154Q | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV50103311; called by muse, mutect2, varscan2
- FRMD1 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs756565455; called by muse, varscan2
- FRMD7 | c.1319G>A p.R440K | Missense Mutation (SNP) | VAF 88/144 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs748910947, COSV53744690; called by muse, mutect2, varscan2
- GABRA5 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 14/125 reads (11%) | catalogued as COSV59483786; called by muse, mutect2, varscan2
- GALNT3 | c.1296T>G p.I432M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV67062064, COSV67062226; called by muse, mutect2, varscan2
- GLI1 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as COSV57365400, COSV57365472; called by muse, mutect2, varscan2
- GRM4 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as COSV65217234; called by muse, mutect2, varscan2
- HOXB1 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53318277; called by muse, mutect2, varscan2
- IL17A | c.291G>T p.L97F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.251); catalogued as COSV100391444; called by muse, mutect2, varscan2
- IL17A | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100391599; called by muse, mutect2, varscan2
- IQGAP2 | c.4024C>A p.R1342S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV57178760; called by muse, mutect2, varscan2
- JPH1 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100646712; called by muse, mutect2
- KCNA1 | c.596C>G p.T199R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV66837998, COSV66838322; called by muse, mutect2, varscan2
- KCNA4 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV60254902; called by muse, mutect2, varscan2
- KCNB2 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV73051863; called by muse, mutect2, varscan2
- KCNH6 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777585947, COSV59006387; called by muse, mutect2, varscan2
- KCNH8 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV60472267; called by muse, mutect2, varscan2
- KCNQ4 | c.1745G>C p.R582P | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61272111, COSV61274576; called by muse, mutect2, varscan2
- KDM4D | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58635754; called by muse, mutect2, varscan2
- KIAA0232 | c.2215G>T p.A739S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs766316465, COSV56928109; called by muse, mutect2, varscan2
- KIF17 | c.2384G>T p.W795L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.906); catalogued as COSV56121208; called by muse, mutect2, varscan2
- KIF21B | c.4443+1G>C p.X1481_splice (on ENST00000422435 / NM_001252100.2; = p.X1468_splice on NM_017596.4) | Splice Site (SNP) | VAF 5/44 reads (11%) | catalogued as COSV59763290; called by muse, mutect2, varscan2
- KRT74 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as rs1177435720, COSV59772965; called by muse, mutect2, varscan2
- KRT77 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV59240914; called by muse, mutect2, varscan2
- L1CAM | c.3028G>C p.G1010R | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV62829494; called by muse, mutect2
- LEF1 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV54471070, COSV99490028; called by muse, mutect2, varscan2
- LGR5 | c.1988G>C p.G663A | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV57008353; called by muse, mutect2, varscan2
- LPCAT4 | c.1361A>T p.E454V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV100149140; called by muse, mutect2, varscan2
- LRP1B | c.876G>T p.W292C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101259125; called by muse, mutect2, varscan2
- LRP1B | c.875G>T p.W292L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101259127, COSV67199918; called by muse, mutect2, varscan2
- LRRC49 | c.714A>T p.R238S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as COSV53013825; called by muse, mutect2, varscan2
- MAG | c.821T>G p.M274R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); catalogued as COSV62702191; called by muse, mutect2
- MAP1B | c.4852T>C p.S1618P | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57103781; called by muse, mutect2, varscan2
- MAP3K19 | c.2720C>A p.S907Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100208998; called by muse, varscan2
- MCTP2 | c.2469G>T p.W823C | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63293462; called by muse, mutect2, varscan2
- MROH5 | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV71302410; called by muse, mutect2, varscan2
- MUC16 | c.35315C>A p.A11772D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.855); catalogued as rs368817262, COSV67482372; called by muse, mutect2, varscan2
- MUC16 | c.13110C>A p.S4370R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.446); catalogued as COSV67482377; called by muse, mutect2, varscan2
- MXRA5 | c.6440G>T p.R2147L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs199912992, COSV54229047, COSV54244657; called by muse, mutect2, varscan2
- MYH11 | c.668C>A p.P223Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55564001; called by muse, mutect2, varscan2
- MYO7A | c.1771C>G p.Q591E | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.801); catalogued as COSV68686333; called by muse, mutect2, varscan2
- MYO7A | c.3975G>T p.Q1325H | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV68686341; called by muse, mutect2, varscan2
- MYOM2 | c.4271A>G p.Y1424C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs769424689, COSV50749500; called by muse, varscan2
- NAV1 | c.4732C>A p.R1578S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV55223125; called by muse, mutect2, varscan2
- NEUROD4 | c.712G>T p.G238W | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54473342; called by muse, mutect2, varscan2
- NEXMIF | c.985A>T p.M329L | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.019); catalogued as COSV50069292; called by muse, mutect2, varscan2
- NOD2 | c.2895C>A p.N965K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100318777; called by muse, mutect2
- NPAS4 | c.1304C>A p.A435D | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV60651929; called by muse, mutect2
- NPR1 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1303123978, COSV64117337; called by muse, mutect2, varscan2
- NSD3 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs752707421, COSV57620031; called by muse, mutect2, varscan2
- NUBPL | c.504G>T p.L168F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV99810096; called by muse, mutect2, varscan2
- OR10J5 | c.718T>A p.C240S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58387208; called by muse, mutect2
- OR52A5 | c.662A>T p.Y221F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56616191; called by muse, mutect2, varscan2
- OR5B3 | c.469C>A p.H157N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.114); catalogued as COSV58678282; called by muse, mutect2, varscan2
- P2RY8 | c.958A>T p.T320S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV67177963; called by muse, mutect2, varscan2
- PALLD | c.1152A>G p.P384= | Splice Region (SNP) | VAF 25/113 reads (22%) | catalogued as rs774645499, COSV54989802; called by muse, mutect2, varscan2
- PCARE | c.535C>G p.P179A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.592); catalogued as COSV59056750; called by muse, mutect2, varscan2
- PCDH18 | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61270897; called by muse, mutect2, varscan2
- PCDHA6 | c.2186A>T p.E729V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV65346377; called by muse, mutect2, varscan2
- PCDHB16 | c.953G>C p.R318P | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53368175; called by muse, mutect2, varscan2
- PCDHGA4 | c.1511C>A p.S504Y | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV54002747; called by muse, mutect2, varscan2
- PCDHGA6 | c.2167C>A p.R723S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); catalogued as COSV54002766; called by muse, mutect2, varscan2
- PCNX1 | c.5548G>A p.V1850I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV53099327; called by muse, mutect2, varscan2
- PFKL | c.1763G>T p.G588V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751862472, COSV60363869; called by muse, mutect2, varscan2
- PLK4 | c.206A>G p.H69R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54638716; called by muse, mutect2
- PLXDC2 | c.473G>T p.R158I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV65907194; called by muse, mutect2, varscan2
- PSAP | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV67550966; called by muse, mutect2, varscan2
- PTCHD3 | c.1725T>A p.D575E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as COSV71257180; called by muse, mutect2, varscan2
- REG3A | c.336C>T p.G112= | Splice Region (SNP) | VAF 35/90 reads (39%) | catalogued as COSV59410954; called by muse, varscan2
- RFFL | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.904); catalogued as rs778758723, COSV52073371, COSV52074794; called by muse, mutect2, varscan2
- RP1L1 | c.5171A>T p.Q1724L | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV66758594; called by muse, mutect2, varscan2
- RYR3 | c.348C>A p.S116R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101213540; called by muse, varscan2
- SALL1 | c.2743G>A p.G915S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.792); catalogued as COSV51762161; called by muse, varscan2
- SDK1 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.101); catalogued as COSV67382553; called by muse, mutect2, varscan2
- SEPTIN14 | c.73C>A p.R25S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66426116, COSV66429912; called by muse, mutect2, varscan2
- SKIDA1 | c.2190G>T p.L730F | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.13); catalogued as COSV71611090; called by muse, mutect2, varscan2
- SLC25A52 | c.598T>G p.F200V (on ENST00000672005; = p.F190V on NM_001034172.4) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52503619; called by muse, mutect2
- SLC2A7 | c.1510G>T p.A504S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV68901506; called by muse, mutect2, varscan2
- SLCO1B1 | c.1925T>C p.I642T | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV57014941; called by muse, mutect2, varscan2
- SLCO5A1 | c.1640C>A p.P547H | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV52665009; called by muse, mutect2, varscan2
- STAC | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV99830477; called by muse, mutect2, varscan2
- STK11 | c.503del p.H168Lfs*119 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as COSV58820092, COSV58821510; called by mutect2, varscan2
- STON1-GTF2A1L | c.3080T>C p.V1027A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as COSV59135320; called by muse, mutect2
- TAF1L | c.3857G>A p.C1286Y | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54266486; called by muse, mutect2, varscan2
- TBRG4 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV51833935; called by muse, mutect2, varscan2
- TESPA1 | c.778C>A p.H260N (on ENST00000316577 / NM_001098815.3; = p.H122N on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV57260462; called by muse, varscan2
- TFPT | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57838182; called by muse, mutect2, varscan2
- THSD7A | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs535672503, COSV70267019; called by muse, mutect2, varscan2
- TMEM132D | c.1520C>A p.T507N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV67161708; called by muse, mutect2, varscan2
- TMEM30A | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100034966; called by muse, mutect2, varscan2
- TMPRSS15 | c.1922-2A>G p.X641_splice | Splice Site (SNP) | VAF 20/40 reads (50%) | catalogued as COSV53045596; called by muse, mutect2, varscan2
- TMTC1 | c.1093G>A p.A365T (on ENST00000539277 / NM_001193451.2; = p.A257T on NM_175861.3) | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV55489737; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs1479682078, COSV59529198; called by muse, mutect2, varscan2
- TOM1 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV65899084; called by muse, mutect2, varscan2
- TRAT1 | c.317C>A p.T106K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.058); catalogued as COSV55470133; called by muse, mutect2, varscan2
- TRIM55 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV52549359; called by muse, mutect2, varscan2
- TSSK4 | c.654C>A p.F218L | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.179); catalogued as COSV55304526; called by muse, mutect2, varscan2
- UBAP2 | c.2605T>G p.F869V | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV54291810; called by muse, mutect2
- UFD1 | c.659C>G p.A220G | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV54252567; called by muse, mutect2, varscan2
- UGGT1 | c.263C>A p.S88* | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as COSV99390998; called by muse, mutect2, varscan2
- UGT2B15 | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426353376, COSV57735917, COSV57737140; called by muse, mutect2, varscan2
- UNC45B | c.2081C>A p.A694E | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV52099116; called by muse, mutect2, varscan2
- VIT | c.1015G>A p.D339N (on ENST00000389975 / NM_001177969.1; = p.D354N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as COSV64898423; called by muse, mutect2, varscan2
- WNK2 | c.2401G>A p.V801M | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.38); catalogued as rs766089132, COSV52954228; called by muse, mutect2, varscan2
- ZBTB7B | c.1199G>T p.R400L (on ENST00000292176; = p.R434L on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV52694182; called by muse, mutect2, varscan2
- ZDHHC21 | c.366G>T p.W122C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs375481310; called by muse, mutect2, varscan2
- ZDHHC9 | c.784G>T p.G262* | Nonsense Mutation (SNP) | VAF 20/29 reads (69%) | catalogued as COSV64097186; called by muse, mutect2, varscan2
- ZFHX4 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 96/289 reads (33%) | catalogued as COSV51483834; called by muse, mutect2, varscan2
- ZFHX4 | c.4654C>G p.Q1552E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50915642, COSV51483861; called by muse, mutect2
- ZFP2 | c.1205G>C p.R402T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV63724771, COSV63726008, COSV63726538; called by muse, varscan2
- ZNF331 | c.1214A>T p.H405L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53478874; called by muse, mutect2, varscan2
- ZNF394 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV58744055; called by muse, mutect2, varscan2
- ZNF582 | c.1494A>T p.R498S | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV56733280; called by muse, mutect2, varscan2
- ZNF649 | c.970G>T p.G324* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV56817259; called by muse, mutect2, varscan2
- ZNF718 | c.1310A>T p.H437L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV68140580; called by muse, mutect2, varscan2
- ZZEF1 | c.2891T>A p.F964Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV67559380; called by muse, mutect2, varscan2
- CNTN6 | c.354del p.F118Lfs*81 | Frame Shift Del (DEL) | VAF 52/138 reads (38%) | called by mutect2, pindel, varscan2
- CSMD3 | c.8668_8669delinsTTT p.G2890Ffs*5 (on ENST00000297405 / NM_001363185.1; = p.G2721Ffs*5 on NM_052900.3) | Frame Shift Ins (INS) | VAF 23/119 reads (19%) | called by pindel, varscan2*
- HOXC8 | c.258del p.K87Nfs*43 | Frame Shift Del (DEL) | VAF 80/285 reads (28%) | called by mutect2, pindel, varscan2
- IGHG2 | c.705G>C p.E235D | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGKV1D-16 | c.227T>G p.L76W | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACTL9 | c.306C>A p.A102= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV61006751; called by muse, mutect2, varscan2
- ACTRT3 | c.741C>A p.L247= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV57754974; called by muse, mutect2, varscan2
- ADAMTS3 | c.1629G>A p.K543= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV104378757, COSV54389674; called by muse, mutect2, varscan2
- AGBL2 | c.1407C>T p.S469= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV54094451; called by muse, mutect2, varscan2
- ATP6AP1 | c.1242C>T p.Y414= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs371590913, COSV63896102; called by muse, mutect2
- BCL11A | c.174G>C p.G58= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100186221; called by muse, mutect2, varscan2
- CAGE1 | c.1857T>C p.S619= (on ENST00000512086; = p.S483= on NM_205864.3) | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV57080401; called by muse, mutect2, varscan2
- CAMTA1 | c.1035C>T p.S345= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV57918808; called by muse, mutect2, varscan2
- EBF3 | c.1557C>T p.Y519= (on ENST00000355311 / NM_001375392.1; = p.Y510= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs147171591; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1128A>G p.Q376= | Silent (SNP) | VAF 112/229 reads (49%) | catalogued as rs983941435, COSV51622260; called by muse, mutect2, varscan2
- FAM120B | c.741A>G p.L247= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as COSV53006937; called by muse, mutect2, varscan2
- FRMD1 | c.40C>A p.R14= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, varscan2
- FRMD1 | c.39C>A p.A13= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, varscan2
- IGHA1 | c.741G>C p.T247= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs776280472; called by muse, mutect2, varscan2
- IQUB | c.1962A>G p.T654= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV61241424; called by muse, varscan2
- MAGEA11 | c.144C>A p.A48= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV60757622; called by muse, mutect2, varscan2
- MYH1 | c.3390G>T p.R1130= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV56847004, COSV56854287; called by muse, mutect2, varscan2
- MYT1L | c.1962T>C p.Y654= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs527880727, COSV67708618; called by muse, mutect2, varscan2
- NEB | c.12393C>T p.S4131= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs746291431, COSV51444068; called by muse, mutect2, varscan2
- NR2F1 | c.897C>A p.I299= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV59069562; called by muse, mutect2, varscan2
- NUP155 | c.87C>T p.L29= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs772659342, COSV51533227; called by muse, mutect2, varscan2
- OR4X1 | c.546G>T p.V182= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV60723534; called by muse, mutect2, varscan2
- PAX1 | c.342C>A p.P114= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV68272880; called by muse, mutect2, varscan2
- PCLO | c.15081A>T p.I5027= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV61655800; called by muse, mutect2
- PLB1 | c.609G>T p.L203= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV59832560; called by muse, mutect2
- PLXNA4 | c.1596G>A p.L532= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs771154818, COSV58150354; called by muse, varscan2
- PRKG2 | c.420T>A p.P140= | Silent (SNP) | VAF 141/432 reads (33%) | catalogued as COSV52329489; called by muse, mutect2, varscan2
- PTK2B | c.2640G>T p.V880= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV57762857; called by muse, mutect2
- SEZ6L | c.1734T>C p.T578= | Silent (SNP) | VAF 57/265 reads (22%) | catalogued as rs1392949526, COSV50675669; called by muse, mutect2, varscan2
- SPTBN4 | c.1413C>T p.H471= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs777037117, COSV58946382; called by mutect2, varscan2
- STAC | c.354C>A p.P118= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV99830483; called by muse, mutect2, varscan2
- STK31 | c.2934A>G p.Q978= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs557373130, COSV63458448; called by muse, mutect2
- TENM2 | c.4368C>T p.C1456= (on ENST00000518659 / NM_001122679.2; = p.C1217= on NM_001080428.3) | Silent (SNP) | VAF 104/287 reads (36%) | catalogued as COSV69125081; called by muse, mutect2, varscan2
- TRMT5 | c.51G>A p.L17= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs755289055, COSV50784697; called by muse, mutect2, varscan2
- TUBA1C | c.198G>T p.V66= | Silent (SNP) | VAF 40/185 reads (22%) | catalogued as rs749099041, COSV56511402; called by muse, mutect2, varscan2
- VIT | c.150C>A p.A50= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV101007646; called by muse, mutect2, varscan2
- ZHX2 | c.1587C>T p.A529= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV58715624; called by muse, mutect2
- C16orf89 | c.-17G>A | 5'UTR (SNP) | VAF 3/11 reads (27%) | catalogued as rs1021783582, COSV60125584; called by muse, mutect2
- LINC00518 | n.904G>T | RNA (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21172397 C>T | 5'Flank (SNP) | VAF 12/60 reads (20%) | catalogued as rs1011343442, COSV101346368, COSV68841251; called by muse, mutect2
- TNNT3 | c.-1C>T | 5'UTR (SNP) | VAF 14/103 reads (14%) | catalogued as rs1284905831, COSV99548683; called by muse, mutect2, varscan2
